MMRF case MMRF_1738 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/559c7791-2a92-46a5-95b7-25325e17b300

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Age at index: 78 years; Vital status: Dead; Days to death: 689 days (1.9 years); Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 78.3 years (28,595 days); ISS stage: III; Days to last known disease status: 689 days (1.9 years); Days to last follow up: 689 days (1.9 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 71 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 93 days; Days to treatment end: 526 days (1.4 years).
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: Third line of therapy; Days to treatment start: 554 days (1.5 years); Days to treatment end: 689 days (1.9 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 689.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 0 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 728 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.1 mg/dL; Immunoglobulin G 4.84 g/L; Immunoglobulin A 2.12 g/L; Immunoglobulin M 0.493 g/L; Beta 2 Microglobulin 6.6 µg/mL; Lactate Dehydrogenase 7.97 µkat/L; Hemoglobin 5.08 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 150 ×10⁹/L; Creatinine 809 µmol/L; Calcium 2.5 mmol/L; Albumin 26 g/L; Total Protein 5.4 g/dL; Glucose 5.89 mmol/L; C-Reactive Protein 6.85 mg/dL.
- Day 86 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 4.29 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.12 mg/dL; Immunoglobulin G 9.07 g/L; Immunoglobulin A 1.42 g/L; Immunoglobulin M 1.48 g/L; Hemoglobin 6.63 mmol/L; Leukocytes 4.54 ×10⁹/L; Absolute Neutrophil 3.46 ×10⁹/L; Platelets 180 ×10⁹/L; Creatinine 63.6 µmol/L; Calcium 2.08 mmol/L; Total Protein 5.4 g/dL; Glucose 5.17 mmol/L.
- Day 174 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 71.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.41 mg/dL; Immunoglobulin G 8.28 g/L; Immunoglobulin A 1.82 g/L; Immunoglobulin M 0.963 g/L; Lactate Dehydrogenase 3.07 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 10.6 ×10⁹/L; Absolute Neutrophil 8.28 ×10⁹/L; Platelets 192 ×10⁹/L; Creatinine 111 µmol/L; Calcium 2.6 mmol/L; Total Protein 5.9 g/dL; Glucose 8.14 mmol/L.
- Day 259: Serum Free Immunoglobulin Light Chain, Kappa 2.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.45 mg/dL; Immunoglobulin G 7.5 g/L; Immunoglobulin A 1.22 g/L; Immunoglobulin M 0.835 g/L; Lactate Dehydrogenase 4.05 µkat/L; Creatinine 57.5 µmol/L; Calcium 2.45 mmol/L; Total Protein 6.8 g/dL; Glucose 5.12 mmol/L.
- Day 323 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 2.89 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.7 mg/dL; Immunoglobulin G 6.42 g/L; Immunoglobulin A 1.25 g/L; Immunoglobulin M 0.752 g/L; Lactate Dehydrogenase 2.2 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 5.18 ×10⁹/L; Absolute Neutrophil 3.73 ×10⁹/L; Platelets 176 ×10⁹/L; Creatinine 65.4 µmol/L; Calcium 2.28 mmol/L; Total Protein 5.5 g/dL; Glucose 6.38 mmol/L.
- Day 476 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 14.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.908 mg/dL; Immunoglobulin G 6.99 g/L; Immunoglobulin A 1.18 g/L; Immunoglobulin M 0.759 g/L; Lactate Dehydrogenase 2.93 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 5.16 ×10⁹/L; Absolute Neutrophil 3.67 ×10⁹/L; Platelets 176 ×10⁹/L; Creatinine 62.8 µmol/L; Calcium 2.4 mmol/L; Total Protein 6.1 g/dL; Glucose 5.28 mmol/L.
- Day 547 (ECOG 1): Immunoglobulin G 7.68 g/L; Immunoglobulin A 1.17 g/L; Immunoglobulin M 0.564 g/L; Lactate Dehydrogenase 3.62 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 8.76 ×10⁹/L; Absolute Neutrophil 7.09 ×10⁹/L; Platelets 169 ×10⁹/L; Creatinine 69.8 µmol/L; Calcium 2.43 mmol/L; Total Protein 6.5 g/dL; Glucose 6.55 mmol/L.
- Day 623 (ECOG 1): Immunoglobulin G 5.42 g/L; Immunoglobulin A 0.781 g/L; Immunoglobulin M 0.339 g/L; Lactate Dehydrogenase 2.03 µkat/L; Hemoglobin 6.14 mmol/L; Leukocytes 6.19 ×10⁹/L; Absolute Neutrophil 4.81 ×10⁹/L; Platelets 164 ×10⁹/L; Creatinine 84.9 µmol/L; Calcium 2.25 mmol/L; Total Protein 5.6 g/dL; Glucose 4.79 mmol/L.

Other clinical attributes
- Day 0: Weight: 65 kg; Height: 165 cm.

Biospecimens (2 samples)
- Sample MMRF_1738_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 0 days.
- Sample MMRF_1738_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 0 days.
